CTSP case CTSP-B02E — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3fafa489-0d0e-42f5-9c9f-5a83a5935930

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. EBV positive diffuse large B-cell lymphoma of the elderly: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 51.0 years (18,612 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 1,838 days (5.0 years); Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low-Intermediate Risk.

Biospecimens (1 sample)
- Sample DLBCL11314-sample: Sample type: Tumor; Tissue type: Tumor.
